FM case AD3796 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/d7874954-0d2c-4dd6-88d8-971e0f38858c

Female, 72.8 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the kidney; metastasis biopsied or resected from the ureter. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
